Gene-level copy-number profile of specimen HCM-BROD-0356-C16-85A from HCMI case HCM-BROD-0356-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G2; Age at diagnosis: 66.1 years (24,137 days).
Specimen HCM-BROD-0356-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 472f148a-bc43-44a7-88b9-861589b53fd8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0356-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/a437b3d4-c1b3-4291-9f87-e0e7155ac798

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,702; copy number 2: 38,850; copy number 3: 2,629; copy number 4: 268; copy number 5: 1,112; copy number 6: 84; copy number 7: 46; copy number 8: 87; copy number 9: 3; copy number 14: 53; copy number 18: 2; copy number 19: 1; copy number 22: 2; copy number 24: 3; copy number 25: 3; copy number 29: 2; copy number 34: 45.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,443 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:94,725,674–95,580,769, 53 genes, copy number 8: CNN2P11, GXYLT1P7, CNN2P8, AC073464.2, CYP4F32P, AC073464.1, SNX18P14, ANKRD20A8P, RNU6-1320P, SOWAHCP5, AC097374.1, TEKT4, MTCO1P48, MTCO3P45, RPS24P6, AC103563.3, AC103563.4, AC103563.5, AC103563.1, AC103563.6, AC103563.8, RN7SL575P, AC103563.7, MAL, AC103563.2, MRPS5, ZNF514, ZNF2, SLC2AXP1, AC092835.1, PROM2, KCNIP3, FABP7P2, FAHD2A, AC009238.3, AC009238.2, AC009238.1, UBTFL5, AC133104.2, AC133104.1, TRIM43B, AC009237.11, AC009237.1, AC009237.10, AC009237.2, TRIM64FP, AC009237.14, AC009237.3, AC009237.8, AC009237.15, AC009237.5, OR7E102P, TRIM51JP.
- chr2:101,696,850–102,533,972, 15 genes, copy number 7: MAP4K4, LINC01127, IL1R2, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4.
- chr2:109,124,357–109,128,930, 2 genes, copy number 8: Metazoa_SRP, SH3RF3-AS1.
- chr2:109,542,799–109,618,990, 4 genes, copy number 7: SEPTIN10, RPL37P12, AC011753.2, SOWAHC.
- chr3:168,249,522–170,305,977, 41 genes, copy number 5: EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA.
- chr3:170,418,868–171,054,973, 16 genes, copy number 5: CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2.
- chr3:171,600,404–172,401,669, 8 genes, copy number 5 (within-gene range 4–5): PLD1, TMEM212-AS1, TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P.
- chr3:172,425,850–173,141,235, 16 genes, copy number 5: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16.
- chr3:177,294,442–177,349,166, 3 genes, copy number 5: LINC00501, ASS1P7, AC117465.1.
- chr3:193,740,471–193,740,715, 1 gene, copy number 5: RN7SL447P.
- chr3:196,527,339–196,832,647, 12 genes, copy number 5: AC092933.1, RPS29P3, WDR53, FBXO45, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P.
- chr11:1,734,821–1,804,095, 7 genes, copy number 6 (within-gene range 4–6): AC068580.4, CTSD, AC068580.3, AC068580.1, AC068580.2, RPL36AP39, AC139143.1.
- chr11:23,478,068–23,480,430, 1 gene, copy number 5: THAP12P4.
- chr12:49,292,631–51,812,864, 89 genes, copy number 5 (broad region; genes not listed).
- chr12:51,817,899–51,820,150, 1 gene, copy number 5: AC068987.3.
- chr12:60,092,864–60,269,686, 3 genes, copy number 5–7: AC080011.1, AC087883.2, AC087883.1.
- chr12:61,231,159–72,186,618, 221 genes, copy number 5–34 (within-gene range 3–34) (broad region; genes not listed).
- chr12:114,682,292–114,771,851, 4 genes, copy number 7 (within-gene range 4–7): AC026765.3, AC026765.4, AC026765.1, AC026765.2.
- chr12:115,569,394–118,430,699, 55 genes, copy number 7–9: AC009803.2, AC009803.1, UBA52P7, RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1, AC079384.1, MIR4472-2, LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2, AC125603.1, SPRING1, RNFT2, AC090013.1, RNU6-558P, AC083806.3, HRK, AC083806.1, FBXW8, AC083806.2, AC127164.1, AC026368.1, TESC, TESC-AS1, FBXO21, NOS1, ELOCP32, AC073864.1, KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1, PEBP1, TAOK3, RPS2P5, AC026367.1, SUDS3, AC026367.3, AC026367.2.
- chr13:101,053,776–102,402,457, 10 genes, copy number 5–8 (within-gene range 1–8): NALCN, ITGBL1, FGF14, AL160153.1, RNU1-24P, HMGB3P7, MIR2681, LIPT1P1, RNY1P2, MIR4705.
- chr20:1,888,128–2,341,079, 11 genes, copy number 5: AL117335.1, SIRPA, PDYN-AS1, PDYN, RPL7P2, STK35, AL359916.1, AL121899.4, AL121899.1, AL121899.2, TGM3.
- chr20:30,214,765–64,327,972, 870 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,919. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
